Somatic mutation profile of tumor specimen C3N-00704-01 (aliquot CPT0055100010) from CPTAC case C3N-00704, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.1 years (24,887 days).
Specimen C3N-00704-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 160b0d60-8a00-4c58-ab6d-46a59b44ab57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00704-71 (Blood Derived Normal), aliquot CPT0062910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6df16a2-a0f5-4745-a73e-e5c60965e5b7

The open-access MAF lists 747 somatic variants for this specimen: 536 protein-altering or splice-affecting, 122 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 463, Silent 122, Intron 44, Nonsense Mutation 34, RNA 18, Frame Shift Del 15, Splice Site 12, 3'UTR 10, 5'UTR 7, 3'Flank 6, Frame Shift Ins 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 77/263 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 73/286 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3778G>A p.D1260N (on ENST00000272895 / NM_173076.3; = p.D942N on NM_015657.3) | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55954982; called by muse, varscan2
- ABCB1 | c.1727C>G p.A576G | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1169358648; called by muse, mutect2, varscan2
- ABCB5 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99033838; called by muse, mutect2, varscan2
- ACSM2B | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61660225; called by muse, mutect2, varscan2
- ACVR2B | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 83/427 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as rs377679317; called by muse, mutect2, varscan2
- ADAMTS20 | c.3648G>T p.W1216C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67134393; called by muse, mutect2, varscan2
- ADAMTS20 | c.3647G>C p.W1216S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67134761; called by muse, mutect2, varscan2
- ADAMTS4 | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63489947; called by muse, mutect2, varscan2
- ADCY2 | c.1157T>A p.V386E | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57872513; called by muse, mutect2, varscan2
- ADGRB3 | c.3149G>A p.R1050K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV53242182; called by muse, mutect2, varscan2
- ADGRG5 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV61083365; called by muse, mutect2, varscan2
- AHNAK2 | c.7181G>A p.G2394E | Missense Mutation (SNP) | VAF 94/463 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs555439758; called by muse, mutect2, varscan2
- AKNAD1 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.4); catalogued as COSV62196077; called by muse, mutect2, varscan2
- ARFGAP3 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1201715045; called by muse, mutect2, varscan2
- ARFGEF1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99143108; called by muse, mutect2, varscan2
- ATP1A2 | c.1965-2A>G p.X655_splice | Splice Site (SNP) | VAF 86/539 reads (16%) | catalogued as rs746362740; called by muse, mutect2, varscan2
- AURKC | c.136G>T p.G46W (on ENST00000302804 / NM_001015878.2; = p.G12W on NM_003160.3) | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57141101; called by muse, mutect2, varscan2
- BAG5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs757492335, COSV54570293; called by muse, mutect2, varscan2
- C1orf216 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52050365; called by muse, mutect2, varscan2
- C4orf54 | c.2280C>G p.S760R | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as rs1409706446; called by muse, mutect2, varscan2
- C6 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as COSV54718057; called by muse, mutect2, varscan2
- CABIN1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs773327324, COSV54082476; called by muse, mutect2, varscan2
- CAMSAP2 | c.718C>T p.P240S (on ENST00000236925 / NM_001297707.2; = p.P229S on NM_203459.3) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52671459; called by muse, mutect2, varscan2
- CBLN1 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54653889; called by muse, mutect2
- CD1E | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs150649106, COSV63772043; called by muse, mutect2, varscan2
- CDH7 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV59894152; called by muse, mutect2, varscan2
- CDH9 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV50257873; called by muse, mutect2, varscan2
- CDHR3 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58415672; called by muse, varscan2
- CFAP47 | c.8762G>T p.G2921V | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs781868486, COSV66217876; called by muse, mutect2, varscan2
- CHADL | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs1413620431; called by muse, mutect2, varscan2
- CHD9 | c.2512-1G>C p.X838_splice | Splice Site (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99529114; called by muse, mutect2
- CHL1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs752032870, COSV56598659; called by muse, mutect2, varscan2
- CHL1 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as COSV56604528; called by muse, mutect2, varscan2
- CHL1 | c.1313G>A p.G438E (on ENST00000397491 / NM_001253387.1; = p.G454E on NM_006614.4) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56606743; called by muse, mutect2, varscan2
- CLK3 | c.1066del p.I356Sfs*14 (on ENST00000395066 / NM_001130028.1; = p.I208Sfs*14 on NM_003992.4) | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs1272725768; called by mutect2, pindel, varscan2
- CNTNAP2 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV62263452; called by muse, mutect2, varscan2
- CNTNAP5 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV70515547; called by muse, mutect2, varscan2
- COL11A1 | c.3862G>T p.G1288* | Nonsense Mutation (SNP) | VAF 50/288 reads (17%) | catalogued as COSV62184775; called by muse, mutect2, varscan2
- COL4A5 | c.4351G>T p.G1451C | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM970368, COSV60358613; called by muse, mutect2, varscan2
- COL4A6 | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1006014823; called by muse, mutect2, varscan2
- CRACD | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99948265; called by muse, mutect2, varscan2
- CTNND2 | c.3613C>A p.R1205S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100481721; called by muse, mutect2, varscan2
- CYLC1 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.25); catalogued as rs888520784; called by muse, mutect2, varscan2
- CYP2C19 | c.1309G>T p.G437* | Nonsense Mutation (SNP) | VAF 29/171 reads (17%) | catalogued as rs1437042029; called by muse, mutect2, varscan2
- DNAH11 | c.6042-1G>T p.X2014_splice | Splice Site (SNP) | VAF 20/158 reads (13%) | catalogued as rs1364430470, COSV100181184; called by muse, varscan2
- DOCK10 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 74/471 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV99286980; called by muse, varscan2
- DOCK2 | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56963590; called by muse, mutect2, varscan2
- DOCK8 | c.5041G>T p.D1681Y | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV66617442; called by muse, mutect2, varscan2
- ERC2 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55640574; called by muse, mutect2, varscan2
- F13A1 | c.1113-1G>T p.X371_splice | Splice Site (SNP) | VAF 106/554 reads (19%) | catalogued as COSV99344265; called by muse, mutect2, varscan2
- FAM135B | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV99357684; called by muse, mutect2, varscan2
- FAM184B | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs1368964051; called by muse, mutect2, varscan2
- FAM83B | c.2247G>T p.E749D | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100174299; called by muse, varscan2
- FCN1 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV65662889; called by muse, mutect2, varscan2
- FLG | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 99/677 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1158060089, COSV100911529; called by muse, mutect2, varscan2
- FLNC | c.7084G>C p.E2362Q | Missense Mutation (SNP) | VAF 66/572 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.796); catalogued as COSV100367509; called by muse, mutect2, varscan2
- FOXRED2 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV99341230; called by muse, mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | catalogued as rs755234663; called by mutect2, varscan2
- GABRA2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99061185; called by muse, mutect2, varscan2
- GAPVD1 | c.2453C>T p.P818L (on ENST00000394104; = p.P845L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV99783935; called by muse, mutect2, varscan2
- GBA | c.413del p.P138Lfs*62 | Frame Shift Del (DEL) | VAF 208/679 reads (31%) | catalogued as CD134814, COSV59170743; called by mutect2, pindel, varscan2
- GLRB | c.817del p.V273Sfs*54 | Frame Shift Del (DEL) | VAF 68/398 reads (17%) | catalogued as rs753915588, COSV52417708, COSV52420097; called by mutect2, pindel, varscan2
- GRIA2 | c.1321C>A p.R441S | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); catalogued as COSV52381359; called by muse, mutect2, varscan2
- GRM3 | c.1888T>A p.F630I | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs754710321; called by muse, mutect2, varscan2
- HAL | c.411+1G>T p.X137_splice | Splice Site (SNP) | VAF 97/355 reads (27%) | catalogued as rs778328756; called by muse, mutect2, varscan2
- HTR3A | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373069618; called by muse, mutect2, varscan2
- IFI27L1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV101267196; called by muse, mutect2, varscan2
- IFI27L2 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53128447; called by muse, mutect2, varscan2
- IFNA8 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1211255207; called by muse, mutect2, varscan2
- IGKV1-6 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 64/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1160627880; called by muse, mutect2, varscan2
- IL18RAP | c.458C>A p.A153E | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs760334912; called by muse, mutect2, varscan2
- IL1RL2 | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.077); catalogued as COSV51820165; called by muse, mutect2, varscan2
- IL23R | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 77/463 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV61375680; called by muse, mutect2, varscan2
- IL4R | c.1667G>T p.R556L | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV50139795; called by muse, mutect2, varscan2
- INSYN2B | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1272187702; called by muse, mutect2, varscan2
- ITGA6 | c.3187G>A p.A1063T (on ENST00000442250; = p.A1024T on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/498 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs374953548; called by muse, mutect2, varscan2
- ITK | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV101439682; called by muse, mutect2, varscan2
- ITPR3 | c.3325G>T p.V1109L | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV65411870; called by muse, mutect2, varscan2
- IWS1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as rs759512960; called by muse, mutect2, varscan2
- KALRN | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV53761979; called by muse, mutect2, varscan2
- KCNA4 | c.1094C>G p.T365R | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs765835735, COSV100069193; called by muse, mutect2, varscan2
- KCNU1 | c.539C>A p.P180Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67758935; called by muse, mutect2, varscan2
- LAIR1 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57307126; called by muse, mutect2, varscan2
- LRRC6 | c.981G>T p.M327I | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV51541510; called by muse, mutect2, varscan2
- MAGEC1 | c.1531C>G p.Q511E | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV99596091; called by muse, mutect2, varscan2
- MAGEC2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV55997721; called by muse, mutect2, varscan2
- MAP2K3 | c.98C>A p.P33Q (on ENST00000342679 / NM_145109.3; = p.P4Q on NM_002756.4) | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.159); catalogued as rs1391649195, COSV57563035; called by muse, mutect2
- MAPK8 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs775931291; called by muse, mutect2, varscan2
- MDGA2 | c.1549C>G p.Q517E (on ENST00000399232 / NM_001113498.2; = p.Q219E on NM_182830.4) | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.137); catalogued as COSV100638641; called by muse, mutect2, varscan2
- MINDY4B | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as rs1014411296; called by muse, mutect2, varscan2
- MLNR | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs1362445968; called by muse, mutect2, varscan2
- MRGPRE | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs957686838; called by muse, mutect2, varscan2
- MUC4 | c.11711C>G p.P3904R | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.811); catalogued as rs878968946, COSV57768494; called by muse, mutect2, varscan2
- MYH7 | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 78/474 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs201012865; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- NAALADL2 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs993923083, COSV70795021; called by muse, mutect2, varscan2
- NCAM1 | c.1763C>A p.A588E (on ENST00000316851 / NM_181351.5; = p.A578E on NM_000615.7) | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57516657; called by muse, mutect2, varscan2
- NCBP1 | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs902054154; called by muse, mutect2, varscan2
- NIBAN2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs773683224, COSV64823692; called by muse, mutect2, varscan2
- NTRK1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 189/580 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV62326977; called by muse, mutect2, varscan2
- OR10K1 | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527774086, COSV56870682; called by muse, mutect2, varscan2
- OR10P1 | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59008530; called by muse, mutect2, varscan2
- OR10V1 | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100275662; called by muse, varscan2
- OR10Z1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.861); catalogued as rs199908371; called by muse, varscan2
- OR13C9 | c.516T>A p.N172K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs778745666; called by muse, mutect2, varscan2
- OR1B1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs751041459; called by muse, mutect2
- OR2M5 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63546926; called by muse, mutect2, varscan2
- OR2T3 | c.897C>A p.N299K | Missense Mutation (SNP) | VAF 33/511 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1486425074, COSV100613310; called by muse, mutect2
- OR2T6 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs778273316; called by muse, mutect2, varscan2
- OR4C46 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as rs1346328521, COSV60219124; called by muse, mutect2, varscan2
- OR4N5 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100374076; called by muse, mutect2, varscan2
- OR52B2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs576479650, COSV101603946, COSV101603947; called by mutect2, varscan2
- OR5A1 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57376200; called by muse, mutect2
- OR5L2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs536857563, COSV65723629, COSV65724467; called by muse, mutect2, varscan2
- OR5M8 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772472936; called by muse, mutect2, varscan2
- OR5R1 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100393630; called by muse, mutect2, varscan2
- OR6P1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58108353; called by muse, mutect2, varscan2
- OR7E24 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV71702339; called by muse, mutect2, varscan2
- OR8H1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs191885508, COSV57293032, COSV57293479; called by muse, mutect2, varscan2
- P2RX6 | c.316-2A>G p.X106_splice | Splice Site (SNP) | VAF 52/501 reads (10%) | catalogued as rs773809261; called by muse, mutect2, varscan2
- PAX3 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 91/660 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs769650688; called by muse, mutect2, varscan2
- PDE10A | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV63097805; called by muse, mutect2, varscan2
- PDE1C | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58502796; called by muse, mutect2, varscan2
- PDXDC1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs141392697, COSV55073666; called by muse, mutect2, varscan2
- PGLYRP3 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51951970; called by muse, mutect2, varscan2
- PGM2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as rs372536402; called by muse, mutect2, varscan2
- PHLDB2 | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV67310467; called by muse, mutect2, varscan2
- PHLPP2 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as COSV62424833; called by muse, mutect2, varscan2
- PKD1 | c.12013C>T p.Q4005* (on ENST00000262304 / NM_001009944.3; = p.Q4004* on NM_000296.4) | Nonsense Mutation (SNP) | VAF 32/656 reads (5%) | catalogued as rs1567148587, CM994745; called by muse, mutect2
- PKP3 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs754778202; called by muse, mutect2, varscan2
- POM121 | c.2335G>T p.G779W (on ENST00000434423; = p.G514W on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1554501473; called by mutect2, varscan2
- PRUNE2 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429988941; called by muse, mutect2
- PSG3 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.069); catalogued as rs745853678, COSV100549221; called by muse, mutect2, varscan2
- PSG4 | c.1008C>A p.S336R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs769133726, COSV54933195; called by muse, varscan2
- RBM20 | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65704579; called by muse, mutect2, varscan2
- RGPD3 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1198913863; called by muse, mutect2, varscan2
- ROCK2 | c.3962T>C p.I1321T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.087); catalogued as rs764703058; called by muse, mutect2, varscan2
- SAMD9 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180104, COSV66073665; called by muse, varscan2
- SCN1A | c.2970del p.L990Ffs*3 (on ENST00000303395 / NM_001202435.3; = p.L979Ffs*3 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as CM087897, COSV100322146; called by mutect2, pindel, varscan2
- SCN3A | c.5528G>A p.S1843N | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs778168402; called by muse, mutect2, varscan2
- SCN7A | c.4772G>T p.R1591M | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV101313336; called by muse, mutect2, varscan2
- SETX | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 72/650 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56386949; called by muse, mutect2, varscan2
- SLC6A16 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60028393; called by muse, mutect2
- SLC9A4 | c.1703C>A p.A568D | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs992350486, COSV54840521; called by muse, mutect2, varscan2
- SORCS3 | c.2127+1G>T p.X709_splice | Splice Site (SNP) | VAF 19/126 reads (15%) | catalogued as rs760373074, COSV63795295; called by muse, mutect2, varscan2
- SPEF2 | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs200903448, COSV100609075; called by muse, mutect2, varscan2
- STAB2 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1330447748; called by muse, mutect2, varscan2
- STPG2 | c.1328A>T p.Q443L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV99758524; called by muse, mutect2, varscan2
- SUCLA2 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138724; called by mutect2, varscan2
- SVEP1 | c.6229C>T p.R2077C | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs774374144, COSV52843838; called by muse, mutect2, varscan2
- TCERG1L | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100894274; called by muse, mutect2, varscan2
- TCL1A | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV68085891; called by muse, mutect2, varscan2
- TP53I13 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs762264129; called by muse, mutect2
- TPK1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 74/287 reads (26%) | catalogued as COSV63643805; called by muse, mutect2, varscan2
- TRIM48 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs780685111; called by muse, mutect2, varscan2
- TRIM63 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as COSV65328740; called by muse, mutect2, varscan2
- TRPC1 | c.1249G>A p.G417R (on ENST00000476941 / NM_001251845.2; = p.G383R on NM_003304.4) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV56432299; called by muse, varscan2
- TRPC4 | c.2404C>A p.L802M (on ENST00000379705 / NM_016179.4; = p.L807M on NM_003306.3) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV59006929; called by muse, mutect2, varscan2
- TRPC5OS | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs763887840; called by muse, mutect2, varscan2
- TRPV5 | c.96C>A p.H32Q | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs996867017; called by muse, mutect2
- TTBK2 | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs768354393; called by muse, mutect2, varscan2
- VAV3 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV58389595; called by muse, mutect2, varscan2
- VWA5B2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs1468229019; called by muse, mutect2, varscan2
- VWA8 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 47/242 reads (19%) | catalogued as COSV55704797; called by muse, mutect2, varscan2
- WDR27 | c.1686G>T p.L562F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV100358424; called by muse, mutect2, varscan2
- YY1AP1 | c.433G>A p.E145K (on ENST00000295566 / NM_139118.2; = p.E68K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/630 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763431851, COSV55121496; called by muse, mutect2
- ZFHX4 | c.8423C>A p.T2808K | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50551645; called by muse, mutect2, varscan2
- ZNF534 | c.1111G>T p.E371* (on ENST00000332323 / NM_001143939.3; = p.E358* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV56521213; called by mutect2, varscan2
- ZNF536 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834828; called by muse, mutect2, varscan2
- ZNF644 | c.3016A>T p.T1006S | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.275); catalogued as COSV61347591; called by muse, mutect2, varscan2
- ZNF648 | c.1384C>A p.R462S | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1450885533, COSV60570874; called by muse, mutect2, varscan2
- ZNF676 | c.613G>T p.E205* (on ENST00000650058; = p.E173* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV101236119; called by muse, mutect2, varscan2
- ZNF711 | c.1950G>T p.R650S | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52154884, COSV52158137; called by muse, mutect2, varscan2
- ZNF74 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.598); catalogued as COSV62620150; called by muse, mutect2, varscan2
- ABCA8 | c.1967C>A p.A656E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ABCC8 | c.1916A>C p.Q639P | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCF3 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 36/202 reads (18%) | called by muse, mutect2, varscan2
- ABRA | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ACSM2A | c.990T>A p.H330Q (on ENST00000219054; = p.H251Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ADAM29 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS10 | c.2493T>G p.Y831* | Nonsense Mutation (SNP) | VAF 47/237 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY8 | c.2156C>A p.A719E | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ADGRG2 | c.3022C>T p.R1008W (on ENST00000379869 / NM_001079858.3; = p.R1005W on NM_005756.4) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGBL4 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.5207del p.G1736Afs*14 | Frame Shift Del (DEL) | VAF 94/485 reads (19%) | called by mutect2, pindel, varscan2
- AL441992.2 | c.1326G>T p.R442S | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANK2 | c.7517G>T p.R2506L | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKFN1 | c.1408C>A p.H470N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ANKRD33B | c.1418C>A p.A473D | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ANKRD45 | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANO1 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ANTXRL | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- APC2 | c.4735C>A p.L1579M | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP23 | c.3416-1G>A p.X1139_splice | Splice Site (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ARHGEF12 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ARL15 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSF | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.058); called by muse, mutect2
- ATG2A | c.4275_4276del p.L1426Rfs*121 | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- B3GNT3 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAG5 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- BHLHE40 | c.129A>G p.I43M | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- BRDT | c.2693C>A p.A898D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2
- C14orf132 | c.273G>C p.L91F (on ENST00000553782 / NM_001289139.2; = p.L60F on NM_001252507.3) | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C1QTNF2 | c.452G>A p.G151D (on ENST00000393975; = p.G106D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C1QTNF4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf16 | c.1019T>A p.L340* | Nonsense Mutation (SNP) | VAF 48/306 reads (16%) | called by muse, mutect2, varscan2
- C4orf54 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 44/218 reads (20%) | called by muse, mutect2, varscan2
- C9 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9 | c.611A>T p.Y204F | Missense Mutation (SNP) | VAF 164/572 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- CACNA1I | c.4904C>A p.A1635D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALCR | c.919C>A p.L307M (on ENST00000649521 / NM_001164737.2; = p.L291M on NM_001742.4) | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CALCRL | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAP2 | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, varscan2
- CAPN11 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN13 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- CARNS1 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CCDC115 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CCDC115 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CCDC136 | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CCDC171 | c.3211G>T p.E1071* | Nonsense Mutation (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- CCDC54 | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CCL3 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 33/371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CDH23 | c.4594G>T p.G1532* | Nonsense Mutation (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- CELA2A | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CELF6 | c.737A>T p.Y246F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CEP295 | c.3860G>T p.G1287V | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CERS2 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- CHD1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHM | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCNKB | c.1686G>T p.M562I | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CLDND1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLPTM1L | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 30/327 reads (9%) | called by muse, mutect2
- CLSPN | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMTR1 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMTR2 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- CNBD1 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CNBD1 | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNNM3 | c.134_145del p.G45_W48del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- CNNM3 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, varscan2
- COL4A1 | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A4 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A1 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.6710G>T p.S2237I (on ENST00000312481; = p.S2233I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- COL9A2 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- COLEC10 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CORO1C | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CREM | c.656C>G p.T219R (on ENST00000429130; = p.T186R on NM_181571.3) | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CSMD3 | c.3599_3600insA p.G1201Wfs*2 (on ENST00000297405 / NM_001363185.1; = p.G1097Wfs*2 on NM_052900.3) | Frame Shift Ins (INS) | VAF 84/715 reads (12%) | called by mutect2, pindel
- CTCFL | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2
- CUBN | c.7715G>T p.G2572V | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CWC27 | c.759_760del p.D254Cfs*6 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- DDX1 | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX60 | c.3902C>G p.P1301R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPDC1 | c.1085C>G p.T362S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DEPDC4 | c.474C>A p.Y158* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- DGKB | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); called by muse, mutect2
- DLG2 | c.1745G>T p.R582M | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DMD | c.3840G>T p.K1280N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DMRTA2 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- DNAH7 | c.4084G>T p.A1362S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- DOCK10 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DOT1L | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- DPP10 | c.1427C>G p.T476R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DSCAM | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, varscan2
- DSP | c.7729G>T p.V2577F | Missense Mutation (SNP) | VAF 91/430 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DST | c.6599G>T p.C2200F | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DST | c.1246A>G p.K416E (on ENST00000361203 / NM_001374722.1; = p.K90E on NM_001723.6) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ECPAS | c.4559A>T p.Q1520L | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ECT2 | c.2135G>T p.G712V (on ENST00000392692 / NM_001349098.2; = p.G681V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELOA | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENDOU | c.1085C>A p.S362Y (on ENST00000422538 / NM_001172439.2; = p.S321Y on NM_006025.4) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPSTI1 | c.839A>T p.E280V (on ENST00000398762 / NM_001330543.2; = p.E269V on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ERCC6 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERICH6 | c.1147T>A p.S383T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- EVC | c.2326G>T p.V776L | Missense Mutation (SNP) | VAF 54/463 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FAF1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.028); called by muse, mutect2
- FAM155A | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FAM163A | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM180A | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- FAM214B | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2
- FBL | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- FDX1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGL2 | c.348A>T p.L116F | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FKBP15 | c.1490A>T p.H497L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, varscan2
- FLG | c.7499G>T p.R2500M | Missense Mutation (SNP) | VAF 68/516 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FLNC | c.7772A>T p.K2591M | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FLRT2 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FOXF2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 97/518 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FYB1 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 155/478 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRA2 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- GABRA6 | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- GABRR2 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- GBA3 | c.621_625del p.S207Rfs*31 | Frame Shift Del (DEL) | VAF 33/272 reads (12%) | called by mutect2, pindel
- GDA | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GFI1B | c.376A>T p.M126L | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- GLRA1 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP1BA | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR55 | c.127C>A p.H43N | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPRIN1 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GPX5 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- GRID1 | c.2111C>A p.T704K | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAP1 | c.1847G>T p.G616V (on ENST00000310778 / NM_001367460.1; = p.G564V on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- HAVCR1 | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2
- HBB | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 66/459 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HEATR5B | c.4998A>T p.Q1666H | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- HGF | c.1252A>G p.N418D | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HIBCH | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- HK3 | c.2531T>A p.V844E | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOOK2 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRH3 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- HS3ST2 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- HSD3B1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2
- IGF2BP1 | c.1578C>A p.D526E | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGF2BP1 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 82/619 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV1-9 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGKV1D-16 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IK | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 54/390 reads (14%) | called by muse, mutect2, varscan2
- IL18R1 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL32 | c.563A>T p.Q188L (on ENST00000396890 / NM_001308078.4; = p.Q142L on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/569 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- IL32 | c.565G>A p.A189T (on ENST00000396890 / NM_001308078.4; = p.A143T on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/569 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.255); called by muse, mutect2
- IPPK | c.415-2A>T p.X139_splice | Splice Site (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- IQCA1 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IRGC | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- IRX1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, varscan2
- ITGAM | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITGB2 | c.1796G>T p.C599F (on ENST00000302347; = p.C575F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ITK | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 110/594 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ITLN1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- KANK1 | c.2631G>A p.M877I | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- KAZN | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- KCNA2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNC1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 54/340 reads (16%) | called by muse, mutect2, varscan2
- KCNMB2 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM4C | c.1678-1G>C p.X560_splice | Splice Site (SNP) | VAF 42/286 reads (15%) | called by muse, varscan2
- KIFC3 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLHL30 | c.1405C>A p.L469M | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KRTAP5-8 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- L2HGDH | c.1391A>T p.*464Lext*10 | Nonstop Mutation (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- LAMB1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LILRA1 | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 39/501 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2
- LRP1B | c.5764G>T p.D1922Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.2767C>T p.P923S (on ENST00000651989 / NM_001370785.2; = p.P890S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC70 | c.712A>T p.N238Y | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LRRIQ3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LTBP1 | c.2060G>T p.R687I (on ENST00000404816 / NM_206943.4; = p.R361I on NM_000627.4) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MAMLD1 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K1 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MED16 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGA | c.4739C>G p.P1580R | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MIA3 | c.4295A>G p.D1432G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MPPED1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MS4A14 | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MUC17 | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- MUC2 | c.2390A>T p.E797V | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- MXRA5 | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH1 | c.999G>T p.M333I | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH3 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO16 | c.5314A>T p.T1772S | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3B | c.2407del p.Q803Kfs*62 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- MYO7A | c.6106C>G p.Q2036E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NDRG3 | c.121G>T p.V41L (on ENST00000349004 / NM_032013.4; = p.V29L on NM_022477.4) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NDST3 | c.1542C>G p.I514M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, varscan2
- NELL1 | c.2289C>G p.I763M | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- NLRP9 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NOP9 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NOTCH4 | c.5578C>T p.R1860C | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NPAP1 | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- NPC1L1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPHP4 | c.2716_2717insT p.R906Lfs*10 | Frame Shift Ins (INS) | VAF 19/131 reads (15%) | called by mutect2, pindel*, varscan2
- NPR2 | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NTNG1 | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSCN | c.7223G>T p.R2408L | Missense Mutation (SNP) | VAF 110/408 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OGDHL | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, varscan2
- OR10P1 | c.635T>G p.F212C | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10W1 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11H2 | c.859C>A p.P287T (on ENST00000556246; = p.P298T on NM_001197287.1) | Missense Mutation (SNP) | VAF 46/914 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2F1 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2
- OR4C3 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR4K2 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 40/669 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- OR52N5 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D13 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR5H1 | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OSTM1 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OTUD6A | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 45/227 reads (20%) | called by muse, mutect2, varscan2
- OTUD7A | c.2144G>T p.R715L (on ENST00000307050 / NM_001382637.1; = p.R708L on NM_130901.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PADI6 | c.524A>T p.K175M | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PAPPA | c.745T>A p.Y249N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PARP14 | c.4861G>A p.E1621K | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PASD1 | c.1748T>C p.V583A | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAX1 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PCDHA4 | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PCDHA7 | c.2260A>T p.R754W | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDHGA4 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA8 | c.1775dup p.A593Gfs*74 | Frame Shift Ins (INS) | VAF 73/454 reads (16%) | called by mutect2, pindel, varscan2
- PCNT | c.4732G>C p.V1578L | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCYT1B | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PDZRN3 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- PER1 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHRF1 | c.1510G>T p.D504Y (on ENST00000264555 / NM_001286581.2; = p.D503Y on NM_020901.4) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIEZO2 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PIWIL2 | c.2175G>T p.L725F | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCB3 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PLCE1 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PLCXD3 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.267); called by muse, mutect2
- PLEKHG5 | c.2356C>T p.H786Y (on ENST00000400915 / NM_001042663.3; = p.H749Y on NM_020631.6) | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, varscan2
- PLPPR5 | c.410T>G p.V137G | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PLXNA1 | c.4118G>T p.R1373L | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PNLIPRP1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.164); called by mutect2, varscan2
- POU3F3 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R3A | c.2746T>A p.F916I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R3A | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PPP1R3C | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP2R2B | c.415C>G p.L139V (on ENST00000394409; = p.L205V on NM_181674.2) | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R3C | c.1605C>G p.N535K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2
- PRDM13 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PRDM9 | c.2168G>T p.R723M | Missense Mutation (SNP) | VAF 72/748 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.404); called by muse, varscan2
- PRKACB | c.352T>G p.Y118D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRPF38B | c.1459A>T p.K487* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- PRR23C | c.198_206del p.C67_L69del | In Frame Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel*, varscan2
- PRRC2B | c.3452G>T p.R1151M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PTK7 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- R3HDM1 | c.2149G>C p.G717R | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- RBBP6 | c.4699A>T p.K1567* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- RBP3 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RELN | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIC8A | c.1136G>T p.R379L (on ENST00000526104 / NM_001286134.1; = p.R385L on NM_021932.5) | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RIF1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RIMS2 | c.3185G>T p.R1062M (on ENST00000666250 / NM_001348490.2; = p.R870M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RMND5B | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RNASE13 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF217 | c.569_585del p.G190Efs*116 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- ROCK1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.2422G>T p.G808W | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSF1 | c.3512A>T p.Y1171F | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTL4 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RYR3 | c.10128dup p.G3377Wfs*23 (on ENST00000389232; = p.G3378Wfs*23 on NM_001036.6) | Frame Shift Ins (INS) | VAF 43/218 reads (20%) | called by mutect2, pindel, varscan2
- SAMD9 | c.3451G>A p.A1151T | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9 | c.2263A>T p.R755W | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SCARF2 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDAD1 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SDE2 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEM1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SEMA6A | c.2314C>A p.R772S | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA6A | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SEMA6B | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SEPTIN8 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SERPINI2 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETX | c.6670G>T p.G2224C | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3BP2 | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- SHANK3 | c.2896A>G p.S966G | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHC3 | c.1485A>T p.Q495H | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SKOR1 | c.2164C>A p.R722S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC17A4 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SLC25A47 | c.353T>A p.V118E | Missense Mutation (SNP) | VAF 164/600 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC36A1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SLC38A6 | c.1298T>G p.V433G | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SLC9A3R2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1A2 | c.1793+1G>T p.X598_splice | Splice Site (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- SLX4 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 85/536 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SMG6 | c.350del p.G117Dfs*16 | Frame Shift Del (DEL) | VAF 50/208 reads (24%) | called by mutect2, pindel, varscan2
- SNAP91 | c.2215T>A p.S739T | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SNAPC3 | c.174del p.D60Tfs*4 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- SNX31 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SORL1 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SPATA31A7 | c.419A>T p.E140V | Missense Mutation (SNP) | VAF 95/550 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPATA31E1 | c.2620A>G p.T874A | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPNS3 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPO11 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- STAB1 | c.4855C>A p.P1619T | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STXBP5 | c.3092del p.G1031Vfs*7 (on ENST00000321680 / NM_001127715.2; = p.G995Vfs*7 on NM_139244.4) | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | called by mutect2, pindel
- SYNE1 | c.13029G>T p.L4343F (on ENST00000367255 / NM_182961.4; = p.L4272F on NM_033071.3) | Missense Mutation (SNP) | VAF 124/536 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TAAR1 | c.263G>C p.C88S | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TACC2 | c.7886C>A p.A2629E (on ENST00000334433; = p.A707E on NM_006997.4) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- TANC2 | c.2785G>T p.G929W | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D28 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TCP1 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- TDRD15 | c.2710G>T p.A904S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- TENM2 | c.5803T>C p.S1935P (on ENST00000518659 / NM_001122679.2; = p.S1696P on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TFCP2L1 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGIF2LX | c.34del p.Q12Kfs*175 | Frame Shift Del (DEL) | VAF 103/521 reads (20%) | called by mutect2, pindel, varscan2
- TGIF2LX | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 126/500 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TLL2 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM2D1 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TMEM130 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TMEM132E | c.2398G>T p.G800C (on ENST00000321639; = p.G890C on NM_001304438.2) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM239 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM8B | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM94 | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, varscan2
- TNS1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TPSB2 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRABD2B | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC12 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- TRBV2 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 24/336 reads (7%) | called by muse, mutect2
- TRIM10 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TRIM11 | c.859+5G>T | Splice Region (SNP) | VAF 29/264 reads (11%) | called by mutect2, varscan2
- TRIM11 | c.859+2dup | Splice Region (INS) | VAF 28/278 reads (10%) | called by mutect2, pindel
- TRIM49B | c.1026C>G p.Y342* | Nonsense Mutation (SNP) | VAF 66/386 reads (17%) | called by muse, mutect2, varscan2
- TRIM72 | c.1224G>C p.R408S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- TRPM4 | c.2503G>T p.G835* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- TSPEAR | c.1149+1G>T p.X383_splice | Splice Site (SNP) | VAF 34/192 reads (18%) | called by muse, varscan2
- TSSK1B | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by mutect2, varscan2
- TYW1B | c.1369A>C p.R457= | Splice Region (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- UACA | c.2006G>A p.R669K | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBE2A | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- UBR4 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UGT2B4 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UHRF2 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- UNC5C | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC79 | c.3800C>A p.P1267Q (on ENST00000393151 / NM_001346218.2; = p.P1090Q on NM_020818.5) | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UNC80 | c.8006C>G p.P2669R | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.15509dup p.N5170Kfs*8 | Frame Shift Ins (INS) | VAF 59/488 reads (12%) | called by mutect2, pindel, varscan2
- USH2A | c.4262C>T p.T1421I | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, varscan2
- USH2A | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- UTP11 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- UXS1 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VWA8 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- WDFY4 | c.6378G>A p.W2126* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- WDR24 | c.322C>A p.R108S (on ENST00000248142; = p.R46S on NM_032259.4) | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- WDTC1 | c.1627G>T p.A543S (on ENST00000319394 / NM_001276252.2; = p.A542S on NM_015023.5) | Missense Mutation (SNP) | VAF 67/436 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK2 | c.4834C>T p.P1612S (on ENST00000297954 / NM_001282394.1; = p.P1575S on NM_006648.3) | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XIRP1 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.2954G>A p.G985E (on ENST00000628543; = p.G1160E on NM_152381.6) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- YJU2 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ZBBX | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBED9 | c.1665A>T p.K555N | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF236 | c.1072A>T p.I358F | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF248 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, varscan2
- ZNF518B | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- ZNF607 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- ZNF729 | c.2264T>A p.L755H | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, varscan2
- ZNF804A | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZNF890P | n.698C>A | Splice Region (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- AC099489.1 | c.3306G>T p.T1102= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV100763338; called by muse, mutect2, varscan2
- ADGRA1 | c.1476C>A p.A492= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- ADGRB1 | c.453C>A p.P151= | Silent (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
- AKR1C2 | c.30G>T p.L10= | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- AL049634.2 | c.453G>C p.V151= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- APC2 | c.4734C>A p.S1578= | Silent (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- AQP9 | c.60C>T p.S20= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.219C>T p.P73= | Silent (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- BAG5 | c.810G>C p.L270= | Silent (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- CACNA1E | c.4924C>A p.R1642= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs1294061346, COSV100701959; called by muse, mutect2, varscan2
- CAD | c.6072G>T p.R2024= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- CAPSL | c.102G>T p.L34= | Silent (SNP) | VAF 75/229 reads (33%) | called by muse, mutect2, varscan2
- CCDC27 | c.1521C>G p.L507= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as COSV53901631, COSV53902397; called by muse, mutect2, varscan2
- CDH7 | c.576C>T p.V192= | Silent (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- CHTF18 | c.2520G>C p.T840= | Silent (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- CLCA4 | c.1026C>A p.S342= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.342G>A p.R114= | Silent (SNP) | VAF 42/277 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.3735T>G p.A1245= | Silent (SNP) | VAF 66/1160 reads (6%) | catalogued as COSV52669436; called by muse, mutect2
- CROCC | c.2080C>T p.L694= | Silent (SNP) | VAF 64/699 reads (9%) | catalogued as rs1472972368; called by muse, mutect2
- CYP2E1 | c.114G>T p.P38= | Silent (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- DEFB118 | c.165C>T p.C55= | Silent (SNP) | VAF 61/305 reads (20%) | called by muse, mutect2, varscan2
- DOCK2 | c.3729G>T p.T1243= | Silent (SNP) | VAF 35/281 reads (12%) | catalogued as COSV56974650, COSV99914990; called by muse, mutect2, varscan2
- ECE1 | c.321G>T p.V107= | Silent (SNP) | VAF 81/482 reads (17%) | called by muse, mutect2, varscan2
- EIF3E | c.30C>T p.I10= | Silent (SNP) | VAF 27/222 reads (12%) | catalogued as COSV55201119, COSV55202044, COSV55202459; called by muse, mutect2, varscan2
- ENC1 | c.534C>T p.T178= | Silent (SNP) | VAF 41/245 reads (17%) | called by muse, mutect2, varscan2
- FAF1 | c.1308G>A p.V436= | Silent (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2
- FAM163B | c.85C>A p.R29= | Silent (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- FAM83B | c.1461C>A p.T487= | Silent (SNP) | VAF 31/199 reads (16%) | catalogued as COSV100174200; called by muse, mutect2, varscan2
- FASLG | c.845A>G p.*282= | Silent (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- FAT1 | c.12135A>T p.I4045= | Silent (SNP) | VAF 50/173 reads (29%) | called by muse, varscan2
- FBXO41 | c.153C>A p.A51= | Silent (SNP) | VAF 47/166 reads (28%) | called by muse, mutect2, varscan2
- FCRLA | c.798C>A p.A266= (on ENST00000367959; = p.A243= on NM_032738.4) | Silent (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- GABRA5 | c.819C>A p.I273= | Silent (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- GABRB3 | c.1329C>A p.T443= | Silent (SNP) | VAF 53/238 reads (22%) | catalogued as COSV100157775; called by muse, mutect2, varscan2
- GCH1 | c.276C>G p.L92= | Silent (SNP) | VAF 35/342 reads (10%) | catalogued as rs750601953, CD043796; called by muse, mutect2, varscan2
- GIMAP6 | c.580C>A p.R194= | Silent (SNP) | VAF 42/345 reads (12%) | called by muse, mutect2, varscan2
- GPR50 | c.645G>T p.V215= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs1027259864; called by muse, mutect2, varscan2
- GSG1L | c.780G>T p.R260= (on ENST00000447459 / NM_001109763.2; = p.R105= on NM_144675.2) | Silent (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- HACD2 | c.510A>G p.T170= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1168391807; called by muse, mutect2, varscan2
- HBB | c.87G>A p.L29= | Silent (SNP) | VAF 89/532 reads (17%) | called by muse, mutect2, varscan2
- IPO4 | c.303C>T p.A101= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- IRX1 | c.1050G>A p.A350= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1445451035; called by muse, varscan2
- IVL | c.798G>T p.L266= | Silent (SNP) | VAF 52/161 reads (32%) | called by muse, varscan2
- IZUMO3 | c.24G>T p.L8= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs1031344478; called by muse, mutect2, varscan2
- KCNJ4 | c.183C>A p.I61= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- KLHL14 | c.1002G>C p.P334= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- KPRP | c.771T>A p.P257= | Silent (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
- KRT16 | c.1416C>T p.S472= | Silent (SNP) | VAF 76/400 reads (19%) | catalogued as COSV100052863; called by muse, mutect2, varscan2
- LAMA2 | c.4203G>T p.L1401= | Silent (SNP) | VAF 101/428 reads (24%) | catalogued as rs1217531843; called by muse, mutect2, varscan2
- LARS1 | c.225G>T p.G75= | Silent (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- LBP | c.711G>T p.R237= | Silent (SNP) | VAF 55/207 reads (27%) | called by muse, mutect2, varscan2
- LRP1B | c.9303C>A p.L3101= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV67198113; called by muse, mutect2, varscan2
- LRRIQ3 | c.324G>A p.G108= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs141336710; called by muse, mutect2, varscan2
- LRRTM4 | c.1371C>A p.L457= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1530C>A p.P510= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as COSV99596832; called by muse, mutect2, varscan2
- MAP3K19 | c.417G>T p.R139= | Silent (SNP) | VAF 45/301 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.18501T>C p.L6167= | Silent (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.11313A>T p.P3771= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- MZT2B | c.312G>A p.E104= | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- NCKAP1 | c.3345A>G p.A1115= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs769593811; called by muse, mutect2, varscan2
- NGEF | c.1230C>A p.I410= | Silent (SNP) | VAF 30/195 reads (15%) | catalogued as COSV99890636; called by muse, mutect2, varscan2
- OAS2 | c.303T>A p.T101= | Silent (SNP) | VAF 54/227 reads (24%) | catalogued as rs762170951; called by muse, mutect2, varscan2
- OR10Z1 | c.597C>A p.I199= | Silent (SNP) | VAF 54/346 reads (16%) | catalogued as COSV63526296; called by muse, varscan2
- OR2AJ1 | c.198C>T p.L66= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs535863153; called by muse, mutect2, varscan2
- OR2M5 | c.165C>A p.L55= | Silent (SNP) | VAF 26/211 reads (12%) | catalogued as COSV63547031; called by muse, mutect2, varscan2
- OR2T3 | c.312C>A p.I104= | Silent (SNP) | VAF 44/326 reads (13%) | catalogued as COSV100613239; called by muse, mutect2, varscan2
- OR4C13 | c.159G>T p.L53= | Silent (SNP) | VAF 60/279 reads (22%) | called by muse, mutect2, varscan2
- OR4D1 | c.162G>A p.R54= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as COSV52125750; called by muse, mutect2, varscan2
- OR4K2 | c.663C>A p.V221= | Silent (SNP) | VAF 36/660 reads (5%) | catalogued as COSV53849274; called by muse, mutect2
- OR4N2 | c.168A>T p.T56= | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as COSV60050945; called by muse, mutect2
- OR5A1 | c.660C>A p.S220= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- OR5H15 | c.306T>C p.F102= | Silent (SNP) | VAF 62/293 reads (21%) | called by muse, mutect2, varscan2
- OR8J1 | c.474G>A p.V158= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- OR8U1 | c.672C>T p.A224= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as COSV100163687, COSV56418387; called by muse, varscan2
- PCDHA6 | c.771C>T p.N257= | Silent (SNP) | VAF 55/289 reads (19%) | catalogued as rs368773020; called by muse, mutect2, varscan2
- PCDHB7 | c.2184C>A p.G728= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as COSV99176825; called by muse, mutect2, varscan2
- PGK2 | c.993A>T p.A331= | Silent (SNP) | VAF 61/378 reads (16%) | called by muse, mutect2, varscan2
- PLB1 | c.2940C>T p.N980= | Silent (SNP) | VAF 30/155 reads (19%) | called by muse, mutect2, varscan2
- PLS3 | c.852G>T p.S284= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV99172774; called by muse, mutect2, varscan2
- PLXNA4 | c.2016C>T p.C672= | Silent (SNP) | VAF 32/259 reads (12%) | catalogued as rs753493980; called by muse, mutect2, varscan2
- PLXNB3 | c.273T>G p.P91= | Silent (SNP) | VAF 65/156 reads (42%) | called by muse, mutect2, varscan2
- POTEE | c.1668G>T p.L556= | Silent (SNP) | VAF 58/804 reads (7%) | called by muse, mutect2
- PPFIA2 | c.2346C>G p.L782= | Silent (SNP) | VAF 22/168 reads (13%) | called by muse, varscan2
- PPP3CA | c.1236G>T p.V412= | Silent (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- PRUNE2 | c.585G>T p.L195= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV65029572; called by muse, mutect2
- PTPRF | c.786C>T p.Y262= | Silent (SNP) | VAF 39/222 reads (18%) | catalogued as rs755196035; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRT | c.2382C>A p.A794= | Silent (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- RAB40C | c.489C>T p.V163= | Silent (SNP) | VAF 42/327 reads (13%) | called by muse, mutect2, varscan2
- RASIP1 | c.2676G>T p.R892= | Silent (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- RFPL3 | c.441C>A p.V147= (on ENST00000249007 / NM_001098535.1; = p.V118= on NM_006604.2) | Silent (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- RP1L1 | c.141T>A p.A47= | Silent (SNP) | VAF 52/216 reads (24%) | called by muse, mutect2, varscan2
- RPN2 | c.765G>T p.V255= | Silent (SNP) | VAF 85/335 reads (25%) | called by muse, mutect2, varscan2
- RTL1 | c.3156C>A p.A1052= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- SCN3A | c.3087C>A p.A1029= | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- SCUBE1 | c.1797A>G p.S599= | Silent (SNP) | VAF 81/471 reads (17%) | catalogued as rs1376119938; called by muse, mutect2, varscan2
- SDSL | c.150G>T p.R50= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV100615134; called by muse, mutect2, varscan2
- SEC14L1 | c.762G>T p.L254= | Silent (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- SEC24B | c.393A>T p.L131= | Silent (SNP) | VAF 42/206 reads (20%) | called by muse, mutect2, varscan2
- SETD1A | c.5086C>T p.L1696= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs1219140788, COSV52680107, COSV99352628; called by muse, mutect2, varscan2
- SEZ6L | c.1648C>A p.R550= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs774078967; called by muse, mutect2, varscan2
- SFTPD | c.903A>G p.Q301= | Silent (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3822C>T p.S1274= | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- SHANK1 | c.1722C>A p.S574= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- SORCS3 | c.3027T>A p.P1009= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, varscan2
- SPX | c.196C>A p.R66= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs772766676; called by muse, mutect2, varscan2
- SRMS | c.1338G>A p.P446= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs764818396, COSV99420918; called by muse, mutect2
- SULT1E1 | c.375C>A p.I125= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV56946244, COSV56946933; called by muse, varscan2
- SYT1 | c.585G>A p.E195= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs1055673890; called by muse, mutect2, varscan2
- TANGO6 | c.2037C>T p.S679= | Silent (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- TH | c.285C>T p.P95= (on ENST00000381178 / NM_199292.3; = p.P64= on NM_000360.4) | Silent (SNP) | VAF 43/381 reads (11%) | catalogued as rs767080132; called by muse, mutect2, varscan2
- TLL1 | c.1614T>A p.G538= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- TMEM132C | c.2073C>A p.A691= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV59426456; called by muse, mutect2, varscan2
- TMEM132C | c.2277G>A p.V759= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- TRAF2 | c.414G>T p.A138= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as COSV56038417; called by muse, mutect2, varscan2
- TRIM55 | c.36A>G p.K12= | Silent (SNP) | VAF 63/193 reads (33%) | called by muse, mutect2, varscan2
- TSPAN10 | c.216G>A p.V72= (on ENST00000574882 / NM_001290212.1; = p.V34= on NM_031945.4) | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs749829749; called by muse, varscan2
- TTLL3 | c.1191C>A p.V397= | Silent (SNP) | VAF 63/355 reads (18%) | called by muse, mutect2, varscan2
- XIRP2 | c.5553A>T p.V1851= (on ENST00000628543; = p.V2026= on NM_152381.6) | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV99747082; called by muse, mutect2, varscan2
- XYLT1 | c.1464C>A p.A488= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- ZGRF1 | c.5424G>T p.L1808= | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- ZIC2 | c.1386G>T p.A462= | Silent (SNP) | VAF 40/246 reads (16%) | catalogued as rs1383451056; called by muse, varscan2
- ZNF564 | c.96G>A p.V32= | Silent (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- ABCA2 | c.6264+53G>T | Intron (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- ABCC8 | c.1924-32C>A | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- AC002511.3 | n.177C>A | RNA (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- AC008060.1 | n.349G>T | RNA (SNP) | VAF 97/319 reads (30%) | called by muse, mutect2, varscan2
- AC008060.1 | n.350G>T | RNA (SNP) | VAF 97/317 reads (31%) | called by muse, mutect2, varscan2
- AC083899.1 | n.3323C>T | RNA (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- AGAP7P | n.128C>T | RNA (SNP) | VAF 14/61 reads (23%) | called by mutect2, varscan2
- AGXT | c.595+32C>A | Intron (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2
- ASL | c.-6C>T | 5'UTR (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- ATP2B2 | c.782-6090G>A | Intron (SNP) | VAF 60/210 reads (29%) | catalogued as rs371470144; called by muse, mutect2, varscan2
- ATP6V0A4 | c.-7G>A | 5'UTR (SNP) | VAF 42/451 reads (9%) | called by muse, mutect2
- BLACE | n.1529C>A | RNA (SNP) | VAF 77/233 reads (33%) | called by muse, mutect2, varscan2
- C1orf141 | c.346+1633C>A | Intron (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- C1orf159 | c.-23+27A>T | Intron (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- C2orf80 | c.-84C>A | 5'UTR (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- C4B | chr6:32011196 G>A | 5'Flank (SNP) | VAF 48/629 reads (8%) | catalogued as rs758124168; called by muse, mutect2
- C8orf44-SGK3 | c.-481-1906G>A | Intron (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- CAMKK2 | c.*30G>A | 3'UTR (SNP) | VAF 30/116 reads (26%) | catalogued as rs1335147265; called by muse, mutect2, varscan2
- CICP28 | chr7:56812112 C>A | 3'Flank (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- CLDND1 | c.*873G>T | 3'UTR (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- COLEC11 | c.-26-680C>A | Intron (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12247G>A | Intron (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
- CUX1 | c.1384-31G>T | Intron (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- DCX | c.-22-445G>A | Intron (SNP) | VAF 64/321 reads (20%) | called by muse, mutect2, varscan2
- DGLUCY | c.1701+77G>T | Intron (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- DIPK1B | chr9:136726200 G>A | 3'Flank (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- DNMT1 | c.2847-28T>C | Intron (SNP) | VAF 10/279 reads (4%) | catalogued as rs1285844725; called by muse, mutect2
- EFHC1 | c.723+86G>C | Intron (SNP) | VAF 59/326 reads (18%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.158G>T | RNA (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- FAM161A | c.*950A>T | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- FAM205BP | n.1946C>A | RNA (SNP) | VAF 78/862 reads (9%) | called by muse, mutect2
- FMO9P | n.550C>A | RNA (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2755_*2756del | 3'UTR (DEL) | VAF 2/20 reads (10%) | called by pindel, varscan2
- GATA4 | chr8:11761972 C>T | 3'Flank (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- GHR | c.136+17246C>A | Intron (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- HAND2 | c.*88C>A | 3'UTR (SNP) | VAF 40/257 reads (16%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1568G>T | Intron (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- IGHV1-2 | c.-11_-1del | 5'UTR (DEL) | VAF 32/269 reads (12%) | called by mutect2, pindel
- IL16 | c.1421-578C>G | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- ITGA4 | c.*2061T>A | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- KIF17 | c.2020-40C>T | Intron (SNP) | VAF 40/187 reads (21%) | catalogued as rs1036243043; called by muse, mutect2, varscan2
- KRT18P55 | n.715C>A | RNA (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- KRT6A | c.817-16T>C | Intron (SNP) | VAF 84/487 reads (17%) | called by muse, mutect2, varscan2
- LARP1 | c.2546+536G>T | Intron (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- LINC01193 | n.1437G>T | RNA (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18644C>A | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- LINC01619 | chr12:91993378 G>A | 5'Flank (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- MEIS1 | c.630+20A>T | Intron (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- MGAM2 | c.3183-16T>A | Intron (SNP) | VAF 38/578 reads (7%) | called by muse, mutect2
- MGAT5B | c.69-19G>A | Intron (SNP) | VAF 43/422 reads (10%) | catalogued as rs569753276, COSV56932897; called by muse, mutect2
- MLF1 | c.48-3558G>T | Intron (SNP) | VAF 47/220 reads (21%) | called by muse, mutect2, varscan2
- MYL5 | c.187+104C>A | Intron (SNP) | VAF 28/139 reads (20%) | catalogued as COSV58519852; called by muse, mutect2, varscan2
- MYO7B | c.3193-153G>T | Intron (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- NKAIN4 | c.54+62G>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- NOC2L | c.*31G>C | 3'UTR (SNP) | VAF 36/139 reads (26%) | catalogued as rs374807183; called by muse, mutect2, varscan2
- NOC2LP2 | n.1172C>A | RNA (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2
- NPHP3 | c.670+946G>T | Intron (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- OR2L1P | n.487_489delinsTT | RNA (DEL) | VAF 45/385 reads (12%) | called by pindel, varscan2*
- OR2W5 | n.766T>A | RNA (SNP) | VAF 62/285 reads (22%) | called by muse, mutect2, varscan2
- PCCB | c.183+1760C>T | Intron (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- PDLIM5 | c.920+688_920+706delinsC | Intron (DEL) | VAF 33/198 reads (17%) | called by pindel, varscan2*
- PPA2 | c.656-6678C>T | Intron (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- PRCD | chr17:76545243 C>T | 3'Flank (SNP) | VAF 40/514 reads (8%) | called by muse, mutect2
- RAB18 | c.*288A>G | 3'UTR (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- RNF32 | chr7:156640506 C>A | 5'Flank (SNP) | VAF 9/41 reads (22%) | catalogued as rs773202779; called by muse, mutect2, varscan2
- ROBO2 | c.*46C>G | 3'UTR (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.454C>A | RNA (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- SH2B1 | c.-9G>T | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2
- SH3BP2 | c.1549-40G>T | Intron (SNP) | VAF 44/204 reads (22%) | called by muse, mutect2, varscan2
- SLC1A3 | c.181+4275C>A | Intron (SNP) | VAF 32/214 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18460T>A | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088362 C>G | 3'Flank (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092136 G>T | 3'Flank (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- SRSF11 | c.338-56G>T | Intron (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.3459G>T | RNA (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.8615G>T | RNA (SNP) | VAF 44/357 reads (12%) | called by muse, mutect2, varscan2
- STK19 | c.567+24_567+25delinsT | Intron (DEL) | VAF 26/213 reads (12%) | called by pindel, varscan2*
- SUN2 | c.1190+25C>T | Intron (SNP) | VAF 27/145 reads (19%) | catalogued as rs374226808; called by muse, mutect2, varscan2
- SYT14 | c.*909del | 3'UTR (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- TEKT4P2 | n.1393A>T | RNA (SNP) | VAF 53/498 reads (11%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.497-1222G>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, varscan2
- TRBV4-2 | c.-22C>A | 5'UTR (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- TRBV4-2 | c.-21C>A | 5'UTR (SNP) | VAF 13/258 reads (5%) | catalogued as rs1183172008; called by muse, mutect2
- TRPA1 | c.1364+24T>C | Intron (SNP) | VAF 82/606 reads (14%) | called by muse, mutect2, varscan2
- TRPA1 | c.1364+23A>T | Intron (SNP) | VAF 84/603 reads (14%) | called by muse, mutect2, varscan2
- TWF1 | c.25+335G>T | Intron (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- UBA6 | c.960+30G>T | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- VIM | c.720+10G>T | Intron (SNP) | VAF 126/637 reads (20%) | called by muse, mutect2, varscan2
- Y_RNA | chr1:31507797 G>A | 5'Flank (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
